Somatic mutation profile of tumor specimen 0DJ6KN from CCDI case PBBWRP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 0.8 years (294 days).
Specimen 0DJ6KN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90acedb5-563b-4d48-bcf7-000164e9df3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ6K5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/718b6997-6a30-4c93-bc64-55bdd3289ab2

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO1 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 96/884 reads (11%) | catalogued as rs964554426; called by muse, varscan2
- ATAD3A | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 346/815 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59233299; called by muse, varscan2
- STARD7 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 230/578 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1188799731; called by muse, varscan2
- ELMO1 | c.587C>G p.S196W | Missense Mutation (SNP) | VAF 370/938 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, varscan2
- PTCH1 | c.2561-36_2569del p.X854_splice | Splice Site (DEL) | VAF 120/259 reads (46%) | called by pindel, varscan2
- PTEN | c.853_857dup p.S287Kfs*6 | Frame Shift Ins (INS) | VAF 122/198 reads (62%) | called by pindel, varscan2
